Somatic mutation profile of tumor specimen TARGET-10-PAPDCS-09A (aliquot TARGET-10-PAPDCS-09A-01D) from TARGET case TARGET-10-PAPDCS, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.4 years (1,963 days).
Specimen TARGET-10-PAPDCS-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bd94888-3df1-41cc-b6d9-6f9e31fa22a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPDCS-10A (Blood Derived Normal), aliquot TARGET-10-PAPDCS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/352b33bf-23e3-48dd-b82d-200b1d2c9d4f

The open-access MAF lists 12 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, 5'UTR 2, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs757192342, CM164268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN11A | c.4396C>T p.R1466C | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs902393734; called by muse, mutect2
- SYCP1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV65701291; called by muse, mutect2, varscan2
- ECH1 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KCNJ4 | c.1072A>G p.I358V | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- TBX6 | c.755A>G p.Y252C | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHA10 | c.384C>T p.V128= | Silent (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- KCNIP3 | c.423C>T p.D141= | Silent (SNP) | VAF 54/124 reads (44%) | catalogued as rs769227968; called by muse, mutect2, varscan2
- ABHD18 | c.-1G>A | 5'UTR (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- ADGRL3 | c.583+447C>T | Intron (SNP) | VAF 3/37 reads (8%) | called by muse, mutect2
- SHROOM3 | c.324-159A>G | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, varscan2
- TM2D1 | c.-283G>T | 5'UTR (SNP) | VAF 5/13 reads (38%) | called by muse, mutect2
